Somatic mutation profile of tumor specimen MMRF_1079_2_BM_CD138pos (aliquot MMRF_1079_2_BM_CD138pos_T1_KHS5U_L14262) from MMRF case MMRF_1079, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_1079_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3f44348-5be0-4b60-a996-f8169418f11b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1079_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1079_2_PB_WBC_C3_KHS5U_L14263; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6101e9b-90fb-4491-bf7d-4515e621e883

The open-access MAF lists 189 somatic variants for this specimen: 89 protein-altering or splice-affecting, 23 silent, 77 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, 3'UTR 43, Silent 23, Intron 23, Nonsense Mutation 10, 5'UTR 5, 3'Flank 3, Frame Shift Del 3, RNA 2, Splice Region 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1H | c.2230C>T p.R744* | Nonsense Mutation (SNP) | VAF 46/118 reads (39%) | catalogued as rs1437449624, COSV61983301; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C8A | c.538G>A p.V180I | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.604); catalogued as rs757222387; called by muse, mutect2, varscan2
- CBFB | c.165+1G>C p.X55_splice | Splice Site (SNP) | VAF 23/41 reads (56%) | catalogued as COSV51996680, COSV51997241, COSV51997594, COSV52002060; called by muse, mutect2, varscan2
- CDH18 | c.148C>G p.R50G | Missense Mutation (SNP) | VAF 35/412 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56899350; called by muse, mutect2
- COL11A1 | c.3865G>T p.A1289S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs1212241628, COSV100617510, COSV62189537; called by mutect2, varscan2
- COL6A2 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as rs757488307, COSV100153473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP4Z1 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.216); catalogued as rs1489165239; called by muse, mutect2
- D2HGDH | c.1337C>T p.A446V | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.065); catalogued as rs746956176, CM101392; called by muse, mutect2, varscan2
- FLT4 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.131); catalogued as rs1460398148; called by muse, mutect2
- GEMIN6 | c.126C>T p.A42= | Splice Region (SNP) | VAF 110/291 reads (38%) | catalogued as rs779727449; called by muse, mutect2, varscan2
- GTPBP4 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1473578919; called by muse, mutect2, varscan2
- HDGFL2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs1251382765; called by muse, varscan2
- HS3ST2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 146/333 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as COSV54460373, COSV54463153; called by muse, mutect2, varscan2
- IGHV2-70 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372581706; called by muse, varscan2
- IGHV2-70 | c.99del p.T34Hfs*6 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | catalogued as rs747713826; called by pindel, varscan2
- IGHV2-70 | c.53T>A p.L18* | Nonsense Mutation (SNP) | VAF 38/94 reads (40%) | catalogued as rs546731210; called by muse, varscan2
- IGHV2-70 | c.52T>G p.L18V | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs543742874; called by muse, varscan2
- IGHV4-34 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs587753421; called by muse, mutect2, varscan2
- IGKJ4 | c.36A>C p.K12N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | PolyPhen possibly damaging (0.548); catalogued as rs78964890; called by muse, varscan2
- IGKV4-1 | c.335A>G p.Y112C | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs775128716; called by muse, mutect2, varscan2
- IGLV3-1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as rs371113616; called by muse, varscan2
- IGLV3-1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs368495152; called by muse, varscan2
- IRAK1BP1 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 280/517 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV64047994; called by muse, mutect2, varscan2
- KLK14 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 84/251 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs367549276; called by muse, mutect2, varscan2
- PIEZO2 | c.6542C>T p.P2181L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs192092641; called by muse, mutect2, varscan2
- PREX2 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1437254583; called by muse, mutect2
- TKT | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781993830; called by muse, mutect2
- TLL2 | c.1850A>G p.E617G | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs779804858; called by muse, mutect2, varscan2
- UGGT2 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1056341076, COSV65025355; called by muse, mutect2, varscan2
- USH2A | c.9625G>A p.E3209K | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV56451139; called by muse, mutect2
- ADCY2 | c.2467C>T p.Q823* | Nonsense Mutation (SNP) | VAF 10/185 reads (5%) | called by muse, mutect2
- ANKRD9 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP5F1B | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.097); called by muse, mutect2
- CCDC71 | c.344C>A p.T115K | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2
- CHMP7 | c.260T>G p.V87G | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- COPG1 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CYLD | c.828G>A p.W276* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- CYLD | c.2066T>C p.L689P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DDX49 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- FNBP1 | c.442G>C p.A148P | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FRAS1 | c.1924G>A p.G642R | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- FRMD3 | c.373A>G p.R125G | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GULP1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 175/464 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERPUD1 | c.275C>A p.S92* | Nonsense Mutation (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- HOXC11 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH8 | c.655A>C p.T219P | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- KCNK7 | c.679C>A p.H227N | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- KCNU1 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by mutect2, varscan2
- KRBA1 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- KRTAP10-1 | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- LHCGR | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC4B | c.2005G>C p.A669P | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2
- LRRK2 | c.7265A>G p.N2422S | Missense Mutation (SNP) | VAF 93/263 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- MAP7D2 | c.1448A>G p.K483R | Missense Mutation (SNP) | VAF 5/138 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, mutect2
- MEGF11 | c.1689C>A p.D563E | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MIGA1 | c.785C>G p.T262S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MST1R | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 42/411 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTMR9 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- MUSK | c.2086C>G p.P696A | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NEURL2 | c.793C>A p.H265N | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.995); called by muse, mutect2
- NOTCH2 | c.30G>T p.W10C | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- NRAP | c.3668T>C p.L1223P (on ENST00000359988 / NM_001322945.2; = p.L1188P on NM_006175.4) | Missense Mutation (SNP) | VAF 9/289 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- OR13G1 | c.360T>G p.Y120* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- OR8J3 | c.285T>A p.Y95* | Nonsense Mutation (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- PAIP1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAM | c.2744G>A p.G915E (on ENST00000438793 / NM_001319943.1; = p.G916E on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/221 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PDE5A | c.650C>G p.S217* | Nonsense Mutation (SNP) | VAF 93/271 reads (34%) | called by muse, mutect2, varscan2
- PI4KB | c.2095C>G p.R699G (on ENST00000368873 / NM_001369623.1; = p.R711G on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- PLAC8L1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); called by mutect2, varscan2
- PPP4R3C | c.2026G>T p.E676* | Nonsense Mutation (SNP) | VAF 64/77 reads (83%) | called by muse, mutect2, varscan2
- PSD3 | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 107/304 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- RANBP2 | c.7888G>T p.D2630Y | Missense Mutation (SNP) | VAF 27/332 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2
- RYR2 | c.5407A>G p.S1803G | Missense Mutation (SNP) | VAF 94/330 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM4 | c.3544C>A p.Q1182K | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- SLC22A12 | c.1276_1285+1del | Frame Shift Del (DEL) | VAF 28/96 reads (29%) | called by mutect2, pindel
- SPATA17 | c.1042T>C p.S348P | Missense Mutation (SNP) | VAF 151/276 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SPTAN1 | c.6425C>T p.S2142F | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- STAU2 | c.1192A>C p.K398Q (on ENST00000524300 / NM_001164380.2; = p.K366Q on NM_014393.2) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SYNPR | c.538G>C p.V180L | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- THUMPD1 | c.754G>T p.V252F | Missense Mutation (SNP) | VAF 47/363 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TMEM185A | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 30/257 reads (12%) | called by muse, mutect2, varscan2
- TNFSF9 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 46/666 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- TTC6 | c.1041A>C p.E347D | Missense Mutation (SNP) | VAF 77/164 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TTK | c.2096C>T p.S699F | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TYRP1 | c.200del p.A67Efs*2 | Frame Shift Del (DEL) | VAF 168/337 reads (50%) | called by mutect2, pindel, varscan2
- ZBTB9 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2
- ZNF287 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ZNF614 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF813 | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 132/458 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ACOT7 | c.1032G>A p.V344= (on ENST00000377855 / NM_181864.3; = p.V334= on NM_007274.4) | Silent (SNP) | VAF 36/80 reads (45%) | called by muse, mutect2, varscan2
- ANGPTL4 | c.454C>T p.L152= | Silent (SNP) | VAF 83/276 reads (30%) | called by muse, mutect2, varscan2
- ANKRD9 | c.438C>T p.R146= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1304020991; called by muse, mutect2, varscan2
- AP000812.4 | c.651G>T p.R217= | Silent (SNP) | VAF 22/476 reads (5%) | called by muse, mutect2
- AUTS2 | c.1773C>T p.P591= | Silent (SNP) | VAF 36/126 reads (29%) | called by muse, mutect2, varscan2
- CLSPN | c.2127A>T p.A709= | Silent (SNP) | VAF 11/222 reads (5%) | called by muse, mutect2
- FAM83C | c.186G>A p.R62= | Silent (SNP) | VAF 77/202 reads (38%) | called by muse, mutect2, varscan2
- IGHV3-33 | c.135A>G p.G45= | Silent (SNP) | VAF 97/255 reads (38%) | catalogued as rs770658990; called by muse, mutect2, varscan2
- MANEAL | c.909G>A p.A303= (on ENST00000373045 / NM_001113482.1; = p.A81= on NM_152496.2) | Silent (SNP) | VAF 189/463 reads (41%) | catalogued as rs779950563, COSV61116465; called by muse, mutect2, varscan2
- MARCHF7 | c.642T>C p.S214= | Silent (SNP) | VAF 47/366 reads (13%) | called by muse, mutect2, varscan2
- MCOLN2 | c.552C>T p.N184= | Silent (SNP) | VAF 97/233 reads (42%) | catalogued as rs1471067268; called by muse, mutect2, varscan2
- MPHOSPH10 | c.156A>T p.I52= | Silent (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2
- NR2F1 | c.1014G>A p.A338= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as rs201229023; called by muse, mutect2, varscan2
- OR5H1 | c.585T>C p.N195= | Silent (SNP) | VAF 20/51 reads (39%) | called by muse, varscan2
- PLXDC2 | c.462G>T p.R154= | Silent (SNP) | VAF 77/225 reads (34%) | called by muse, mutect2, varscan2
- RELB | c.1105C>T p.L369= | Silent (SNP) | VAF 51/191 reads (27%) | catalogued as rs777367214; called by muse, mutect2, varscan2
- RGS7 | c.318C>T p.T106= | Silent (SNP) | VAF 35/176 reads (20%) | called by muse, mutect2, varscan2
- SV2B | c.144C>T p.G48= | Silent (SNP) | VAF 81/297 reads (27%) | catalogued as rs773245122, COSV57699882; called by muse, mutect2, varscan2
- SYNE1 | c.9915A>G p.S3305= (on ENST00000367255 / NM_182961.4; = p.S3312= on NM_033071.3) | Silent (SNP) | VAF 155/216 reads (72%) | catalogued as rs764114386; ClinVar: likely benign; called by muse, mutect2, varscan2
- UMAD1 | c.51A>C p.P17= | Silent (SNP) | VAF 88/264 reads (33%) | called by muse, mutect2, varscan2
- WDR55 | c.1038G>T p.R346= | Silent (SNP) | VAF 48/436 reads (11%) | called by muse, mutect2
- WT1 | c.393G>A p.P131= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as rs1229890218; called by muse, mutect2, varscan2
- ZNF549 | c.1611C>T p.V537= (on ENST00000376233 / NM_001199295.2; = p.V524= on NM_153263.2) | Silent (SNP) | VAF 86/310 reads (28%) | catalogued as COSV53724040, COSV53724555; called by muse, mutect2, varscan2
- ABCA8 | c.797+173G>T | Intron (SNP) | VAF 7/20 reads (35%) | called by muse, varscan2
- ADH6 | chr4:99203535 G>A | 3'Flank (SNP) | VAF 21/61 reads (34%) | catalogued as rs569961609; called by muse, mutect2, varscan2
- ADH6 | chr4:99204091 C>G | 3'Flank (SNP) | VAF 40/446 reads (9%) | called by muse, mutect2
- ATG16L2 | c.1623-78G>A | Intron (SNP) | VAF 202/432 reads (47%) | catalogued as COSV58361237; called by muse, mutect2, varscan2
- ATM | c.4909+151G>C | Intron (SNP) | VAF 162/893 reads (18%) | called by muse, mutect2, varscan2
- BTN1A1 | c.*931C>T | 3'UTR (SNP) | VAF 170/561 reads (30%) | called by muse, mutect2, varscan2
- C20orf144 | c.*4C>G | 3'UTR (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- C8orf34-AS1 | n.582C>G | RNA (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- CCDC73 | c.429+2678T>C | Intron (SNP) | VAF 36/132 reads (27%) | called by muse, mutect2, varscan2
- CERS6 | c.*1376T>G | 3'UTR (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- CISD2 | c.103+262A>G | Intron (SNP) | VAF 54/174 reads (31%) | called by muse, varscan2
- CNOT10 | c.2004+249G>A | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- EMILIN2 | c.-80C>G | 5'UTR (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- EMILIN2 | c.-79C>G | 5'UTR (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- ENDOU | c.56-120G>T | Intron (SNP) | VAF 12/30 reads (40%) | called by mutect2, varscan2
- ERC1 | c.*2621C>A | 3'UTR (SNP) | VAF 53/140 reads (38%) | called by muse, mutect2, varscan2
- ERP27 | c.*593A>C | 3'UTR (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- FAM161A | c.184-4424A>T | Intron (SNP) | VAF 2/16 reads (13%) | called by muse, mutect2
- FANCD2 | chr3:10101600 G>T | 3'Flank (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- FBXO33 | c.*1056A>T | 3'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, varscan2
- FMN1 | c.*591A>G | 3'UTR (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- GM2A | c.*2245A>G | 3'UTR (SNP) | VAF 207/705 reads (29%) | called by muse, mutect2, varscan2
- GPR176 | c.*1673A>G | 3'UTR (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2
- GRHL2 | c.*353_*354dup | 3'UTR (INS) | VAF 128/369 reads (35%) | called by mutect2, pindel, varscan2
- GRIA4 | c.247+1662A>C | Intron (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- GSK3A | c.284-142C>T | Intron (SNP) | VAF 25/95 reads (26%) | called by muse, mutect2, varscan2
- GTF3C4 | c.*1654del | 3'UTR (DEL) | VAF 26/105 reads (25%) | called by mutect2, pindel, varscan2
- HDLBP | c.*1322A>G | 3'UTR (SNP) | VAF 110/278 reads (40%) | catalogued as rs1043171681; called by muse, mutect2, varscan2
- HPS3 | c.*869T>G | 3'UTR (SNP) | VAF 102/251 reads (41%) | called by muse, mutect2, varscan2
- KCNN4 | c.1049+50T>C | Intron (SNP) | VAF 24/77 reads (31%) | catalogued as rs1243435200; called by mutect2, varscan2
- KCTD8 | c.-156_-127del | 5'UTR (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel
- KITLG | chr12:88580527 C>T | 5'Flank (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- LRRC15 | c.*3530G>C | 3'UTR (SNP) | VAF 36/112 reads (32%) | called by muse, mutect2, varscan2
- MAJIN | c.147+242C>G | Intron (SNP) | VAF 6/136 reads (4%) | called by muse, mutect2
- MAP3K13 | c.2431-257C>T | Intron (SNP) | VAF 17/196 reads (9%) | called by muse, mutect2
- MFHAS1 | c.*1714C>T | 3'UTR (SNP) | VAF 16/47 reads (34%) | catalogued as rs189950579; called by muse, varscan2
- MMP16 | c.*7G>T | 3'UTR (SNP) | VAF 94/263 reads (36%) | catalogued as COSV99685868, COSV99689285; called by muse, mutect2, varscan2
- MRPL22 | c.196-73A>G | Intron (SNP) | VAF 85/139 reads (61%) | called by muse, mutect2, varscan2
- MTMR1 | c.1656+236G>A | Intron (SNP) | VAF 330/348 reads (95%) | called by muse, mutect2, varscan2
- MYO19 | c.*572A>C | 3'UTR (SNP) | VAF 51/139 reads (37%) | called by muse, mutect2, varscan2
- NEK1 | c.*896T>C | 3'UTR (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2, varscan2
- NISCH | c.1528+1129C>T | Intron (SNP) | VAF 72/181 reads (40%) | called by muse, mutect2, varscan2
- NTN5 | c.*16G>T | 3'UTR (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- NUDT5 | c.*741G>C | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- OAS3 | c.3105-224G>A | Intron (SNP) | VAF 9/67 reads (13%) | catalogued as rs563554722; called by muse, mutect2
- OR2C3 | c.*213T>G | 3'UTR (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- OR2W5 | n.1162C>T | RNA (SNP) | VAF 54/218 reads (25%) | catalogued as rs866689227; called by muse, mutect2, varscan2
- OR6J1 | c.*39A>C | 3'UTR (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- OSBPL3 | c.*510T>C | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
- PACRGL | c.*56+668G>T | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- PARVA | c.*1094C>T | 3'UTR (SNP) | VAF 60/104 reads (58%) | catalogued as rs1345894851; called by muse, mutect2, varscan2
- PIK3CG | c.*1286T>C | 3'UTR (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- PPP2R5E | c.*3775G>A | 3'UTR (SNP) | VAF 14/107 reads (13%) | catalogued as rs980136329; called by muse, mutect2, varscan2
- PRLR | c.*7052G>C | 3'UTR (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- PTPRD | c.541+298T>C | Intron (SNP) | VAF 32/104 reads (31%) | called by muse, mutect2, varscan2
- ROBO4 | c.2056+38_2056+39insT | Intron (INS) | VAF 62/416 reads (15%) | called by mutect2, pindel, varscan2
- RSBN1 | c.*1681T>C | 3'UTR (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- RUBCN | c.*3356C>T | 3'UTR (SNP) | VAF 73/151 reads (48%) | called by muse, mutect2, varscan2
- SCARB2 | c.*2806G>T | 3'UTR (SNP) | VAF 8/106 reads (8%) | catalogued as rs1007613211; called by muse, mutect2
- SMOC1 | c.*539C>T | 3'UTR (SNP) | VAF 10/96 reads (10%) | catalogued as rs1237636777; called by muse, mutect2, varscan2
- SP3 | c.*403G>C | 3'UTR (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- SPICE1 | c.*2235C>T | 3'UTR (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- SUPT5H | c.*27G>A | 3'UTR (SNP) | VAF 89/149 reads (60%) | catalogued as rs771750800; called by muse, mutect2, varscan2
- TBC1D10A | c.417+19G>C | Intron (SNP) | VAF 25/238 reads (11%) | called by muse, mutect2, varscan2
- TES | c.-131G>A | 5'UTR (SNP) | VAF 17/62 reads (27%) | catalogued as rs1335673160; called by muse, mutect2, varscan2
- TGDS | c.*598T>A | 3'UTR (SNP) | VAF 7/10 reads (70%) | catalogued as rs1012283243; called by muse, varscan2
- TIA1 | c.*905T>G | 3'UTR (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- TMCO3 | c.*232A>C | 3'UTR (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- TMEM63C | c.*1725T>C | 3'UTR (SNP) | VAF 16/245 reads (7%) | called by muse, mutect2
- TPD52L2 | c.-19G>A | 5'UTR (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- TRIM29 | c.1135-23A>T | Intron (SNP) | VAF 67/128 reads (52%) | called by muse, mutect2, varscan2
- VGLL3 | c.*1987del | 3'UTR (DEL) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- VPS13D | c.*2255G>A | 3'UTR (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+613G>A | Intron (SNP) | VAF 9/120 reads (8%) | called by muse, mutect2
- ZKSCAN1 | c.*706T>A | 3'UTR (SNP) | VAF 63/231 reads (27%) | called by mutect2, varscan2
- ZKSCAN1 | c.*707C>A | 3'UTR (SNP) | VAF 62/230 reads (27%) | called by mutect2, varscan2
- ZNF662 | c.*185G>A | 3'UTR (SNP) | VAF 5/109 reads (5%) | called by muse, mutect2
